Somatic mutation profile of tumor specimen 0DGJ7N from CCDI case PBBTRA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 5.2 years (1,914 days).
Specimen 0DGJ7N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 313cbea2-4872-4c65-8596-ff92215b8587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGJ61 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b90f79c-e418-4b08-bf7b-468ba640a248

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 3, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A6 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 421/1072 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs1172531183; called by muse, mutect2, varscan2
- GATC | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 321/1325 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV99985017; called by muse, mutect2, varscan2
- HDGFL3 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 30/1026 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100220985; called by muse, mutect2
- MYO7B | c.5125G>A p.E1709K | Missense Mutation (SNP) | VAF 185/1115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450105393; called by muse, mutect2, varscan2
- DIP2B | c.1136T>A p.L379* | Nonsense Mutation (SNP) | VAF 332/656 reads (51%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3574A>G p.T1192A (on ENST00000676171; = p.T1151A on NM_004570.5) | Missense Mutation (SNP) | VAF 351/7076 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRKDC | c.9209A>T p.H3070L | Missense Mutation (SNP) | VAF 155/1061 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, varscan2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 32/840 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- RPLP0 | c.651+8C>T | Splice Region (SNP) | VAF 173/750 reads (23%) | called by muse, varscan2
- CKAP4 | c.1710C>T p.N570= | Silent (SNP) | VAF 441/1203 reads (37%) | called by muse, mutect2, varscan2
- GOLGA3 | c.1473G>T p.L491= | Silent (SNP) | VAF 947/1701 reads (56%) | called by muse, mutect2, varscan2
- PORCN | c.1092C>A p.L364= (on ENST00000326194 / NM_203475.3; = p.L353= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 293/800 reads (37%) | called by muse, mutect2, varscan2
- RNF10 | c.1197G>A p.L399= | Silent (SNP) | VAF 377/1468 reads (26%) | catalogued as rs1469700243; called by muse, mutect2, varscan2
- TMEM132C | c.840C>T p.S280= | Silent (SNP) | VAF 249/572 reads (44%) | catalogued as rs779056883; called by muse, mutect2
- FAM227B | c.51+17A>G | Intron (SNP) | VAF 20/533 reads (4%) | called by muse, mutect2
- PPFIBP1 | c.604-21T>G | Intron (SNP) | VAF 104/3942 reads (3%) | called by muse, mutect2
- YKT6 | c.459+9G>A | Intron (SNP) | VAF 50/1257 reads (4%) | called by muse, mutect2
